Somatic mutation profile of tumor specimen TCGA-CV-7261-01A (aliquot TCGA-CV-7261-01A-11D-2012-08) from TCGA case TCGA-CV-7261, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 57.5 years (20,992 days).
Specimen TCGA-CV-7261-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b5632c18-e65c-4f14-bc49-09bb28da6054.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-7261-10A (Blood Derived Normal), aliquot TCGA-CV-7261-10A-01D-2013-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/beacdbf9-2586-416e-a8eb-e4beacb6fc3c

The open-access MAF lists 104 somatic variants for this specimen: 83 protein-altering or splice-affecting, 19 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 70, Silent 19, Nonsense Mutation 6, Frame Shift Ins 3, RNA 2, Splice Region 1, Translation Start Site 1, Splice Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FUT8 | c.715C>T p.R239* (on ENST00000360689 / NM_001371534.1; = p.R76* on NM_004480.4) | Nonsense Mutation (SNP) | VAF 24/97 reads (25%) | catalogued as rs1460811017, COSV100651384; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MAPK1 | c.964G>T p.E322* | Nonsense Mutation (SNP) | VAF 35/93 reads (38%) | hotspot (GDC flag); catalogued as COSV53184855, COSV99308005; called by muse, mutect2, varscan2
- PIK3CA | c.1094A>T p.E365V | Missense Mutation (SNP) | VAF 47/183 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV55876575; called by muse, mutect2, varscan2
- AC131160.1 | c.1133G>A p.G378E | Missense Mutation (SNP) | VAF 79/161 reads (49%) | SIFT tolerated, low confidence (0.24); PolyPhen probably damaging (0.97); catalogued as COSV100590618; called by muse, mutect2, varscan2
- ACTC1 | c.109G>A p.V37M | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.842); catalogued as rs1407311947, COSV51761484; called by muse, mutect2, varscan2
- ADAM10 | c.833A>G p.N278S | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.232); catalogued as COSV99546138; called by muse, mutect2
- ADAM10 | c.361G>C p.D121H | Missense Mutation (SNP) | VAF 4/53 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); catalogued as COSV99546141, COSV99546273; called by muse, mutect2
- AGTR2 | c.849G>C p.W283C | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.95); catalogued as COSV100903576; called by muse, mutect2, varscan2
- AICDA | c.388C>T p.H130Y | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.284); catalogued as rs1205346812, COSV99984202; called by muse, mutect2, varscan2
- ATP13A4 | c.1927T>G p.F643V | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as COSV99794564; called by muse, mutect2
- BRD4 | c.1847G>A p.R616Q | Missense Mutation (SNP) | VAF 26/127 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99650731; called by muse, mutect2, varscan2
- CACNA1A | c.2014G>A p.E672K | Missense Mutation (SNP) | VAF 14/178 reads (8%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.477); catalogued as rs1434942721, COSV64193791; ClinVar: uncertain significance; called by muse, mutect2
- CAMTA2 | c.946G>A p.G316R | Missense Mutation (SNP) | VAF 25/40 reads (63%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.998); catalogued as COSV100772629; called by muse, mutect2, varscan2
- CCRL2 | c.214G>A p.V72M | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.176); catalogued as rs374019945, COSV100645035; called by muse, mutect2, varscan2
- CD1C | c.653C>T p.S218F | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.216); catalogued as COSV100939342, COSV100939395; called by muse, mutect2
- CFAP46 | c.6055G>A p.E2019K | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.013); catalogued as COSV99583769; called by muse, mutect2, varscan2
- CFAP65 | c.2710C>T p.R904C | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs138095762; called by muse, mutect2, varscan2
- CNTN6 | c.1972T>C p.Y658H | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as rs769596894, COSV63162416; called by mutect2, varscan2
- COQ8B | c.797C>T p.A266V | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT deleterious (0.01); PolyPhen benign (0.19); catalogued as rs766618659, COSV99699435; called by muse, mutect2, varscan2
- DCAF4L2 | c.905C>T p.T302I | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.147); catalogued as COSV100150924; called by muse, mutect2, varscan2
- FCRL1 | c.51C>T p.A17= | Splice Region (SNP) | VAF 18/102 reads (18%) | catalogued as rs781242642, COSV100839793; called by muse, mutect2, varscan2
- FDXACB1 | c.1134G>T p.Q378H | Missense Mutation (SNP) | VAF 13/245 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.275); catalogued as COSV99499902; called by muse, mutect2
- FOXB1 | c.712T>C p.Y238H | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV101249835; called by muse, mutect2, varscan2
- GABRG2 | c.1358A>G p.D453G (on ENST00000361925 / NM_001375343.1; = p.D413G on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.997); catalogued as COSV62720162; called by muse, mutect2, varscan2
- GABRR1 | c.70A>T p.S24C | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as COSV101033933; called by muse, mutect2, varscan2
- GBX1 | c.743C>A p.A248E | Missense Mutation (SNP) | VAF 17/190 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.052); catalogued as COSV52548776, COSV99880901; called by muse, mutect2
- GLI3 | c.1174C>A p.P392T | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0.022); catalogued as COSV101229891; called by muse, mutect2, varscan2
- GMIP | c.689G>A p.R230H | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.767); catalogued as COSV99179301; called by muse, mutect2, varscan2
- GOLGA2 | c.1414C>T p.Q472* | Nonsense Mutation (SNP) | VAF 23/78 reads (29%) | catalogued as COSV101363133; called by muse, mutect2, varscan2
- GPX4 | c.382G>C p.D128H | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as COSV100684583; called by muse, mutect2, varscan2
- HPX | c.1085C>T p.A362V | Missense Mutation (SNP) | VAF 38/64 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as rs779098616, COSV56419680; called by muse, mutect2, varscan2
- IGSF3 | c.2180G>C p.G727A (on ENST00000369486 / NM_001007237.3; = p.G747A on NM_001542.4) | Missense Mutation (SNP) | VAF 35/142 reads (25%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.958); catalogued as COSV100604708; called by muse, mutect2, varscan2
- IQCH | c.1840C>T p.R614C | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV60057163; called by muse, mutect2, varscan2
- JUP | c.193G>C p.V65L | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV100159598, COSV60277953; called by muse, mutect2, varscan2
- KALRN | c.8119C>A p.R2707S (on ENST00000360013 / NM_001024660.4; = p.R1010S on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.33); catalogued as COSV99362178; called by muse, mutect2, varscan2
- KANSL1 | c.2664-1G>A p.X888_splice (on ENST00000574590 / NM_001193465.2; = p.X889_splice on NM_015443.4) | Splice Site (SNP) | VAF 11/39 reads (28%) | catalogued as COSV52274205, COSV99294568; called by muse, mutect2, varscan2
- KIFC2 | c.1324C>T p.R442C | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as rs781565567, COSV100023614; called by muse, mutect2, varscan2
- KLKB1 | c.316C>T p.H106Y | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV99250024; called by mutect2, varscan2
- LRP10 | c.1853T>C p.I618T | Missense Mutation (SNP) | VAF 7/166 reads (4%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV100612389; called by muse, mutect2
- LRP2 | c.7686G>T p.E2562D | Missense Mutation (SNP) | VAF 12/119 reads (10%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV55578135, COSV99788644; called by muse, mutect2, varscan2
- LRRCC1 | c.664G>A p.G222S | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV100835463; called by muse, mutect2, varscan2
- MARF1 | c.2566T>C p.Y856H | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV100705954; called by muse, mutect2, varscan2
- MKI67 | c.6940G>C p.E2314Q | Missense Mutation (SNP) | VAF 66/348 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV100896592; called by muse, mutect2, varscan2
- MSANTD4 | c.884C>T p.T295I | Missense Mutation (SNP) | VAF 16/164 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.146); catalogued as COSV100108596; called by muse, mutect2
- MUC16 | c.35761G>T p.E11921* | Nonsense Mutation (SNP) | VAF 53/148 reads (36%) | catalogued as COSV101200024; called by muse, mutect2, varscan2
- MYO10 | c.3666_3667insT p.G1223Wfs*28 | Frame Shift Ins (INS) | VAF 17/102 reads (17%) | catalogued as COSV57020181; called by mutect2, varscan2
- MYO3A | c.3546C>G p.N1182K | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.205); catalogued as COSV99779855; called by muse, mutect2, varscan2
- NCOA1 | c.456G>C p.M152I | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.291); catalogued as COSV99946155; called by muse, mutect2
- NIN | c.1420G>T p.A474S | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.708); catalogued as COSV99813657; called by mutect2, varscan2
- OR4A15 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 8/55 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.951); catalogued as rs1231271164, COSV100124118; called by mutect2, varscan2
- OR52N4 | c.863C>A p.P288H | Missense Mutation (SNP) | VAF 43/76 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100421682; called by muse, mutect2, varscan2
- OR5I1 | c.755T>C p.I252T | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs748998630, COSV100041444, COSV100041449; called by muse, mutect2, varscan2
- PARP14 | c.1393C>A p.Q465K | Missense Mutation (SNP) | VAF 30/57 reads (53%) | SIFT deleterious (0.03); PolyPhen benign (0.335); catalogued as COSV101506285, COSV71735461; called by muse, mutect2, varscan2
- PEX2 | c.73C>A p.L25I | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100824789; called by muse, mutect2
- PIK3CG | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.164); catalogued as rs1381484125, COSV63247479; called by muse, mutect2, varscan2
- PITPNM1 | c.1901G>A p.S634N | Missense Mutation (SNP) | VAF 11/139 reads (8%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.584); catalogued as COSV100711667; called by muse, mutect2
- PLEKHA1 | c.1210G>A p.V404M | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs751335255, COSV100935497, COSV64570035; called by muse, mutect2, varscan2
- PLXNA1 | c.4711G>T p.E1571* | Nonsense Mutation (SNP) | VAF 18/66 reads (27%) | catalogued as COSV99303167; called by muse, mutect2, varscan2
- POM121L12 | c.742T>G p.C248G | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT tolerated (0.26); PolyPhen benign (0.208); catalogued as COSV101374921, COSV101374957; called by muse, mutect2
- RBM6 | c.2897A>T p.N966I | Missense Mutation (SNP) | VAF 55/126 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99805480; called by muse, mutect2, varscan2
- RFX6 | c.670G>A p.E224K | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.075); catalogued as COSV100263769; called by muse, mutect2, varscan2
- RGS11 | c.1262C>T p.A421V (on ENST00000397770 / NM_183337.3; = p.A400V on NM_003834.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99395817; called by muse, mutect2, varscan2
- RP1 | c.682A>T p.K228* | Nonsense Mutation (SNP) | VAF 13/35 reads (37%) | catalogued as COSV99607605; called by muse, mutect2, varscan2
- RPS6KC1 | c.3062C>G p.S1021C | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100873914; called by muse, mutect2, varscan2
- SERPINH1 | c.838C>T p.R280C | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs200572997, COSV63997891; called by muse, mutect2, varscan2
- SET | c.728G>C p.G243A (on ENST00000372692 / NM_001374326.1; = p.G230A on NM_003011.4) | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as COSV100433117; called by muse, mutect2, varscan2
- SH2D4B | c.238G>T p.V80F | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs376600606; called by muse, mutect2, varscan2
- STARD3NL | c.101T>A p.M34K | Missense Mutation (SNP) | VAF 43/67 reads (64%) | SIFT tolerated (0.29); PolyPhen benign (0.022); catalogued as COSV99151587; called by muse, mutect2, varscan2
- STX11 | c.421C>A p.R141S | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV100845491; called by muse, mutect2, varscan2
- SUPV3L1 | c.776G>T p.R259L | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.473); catalogued as COSV100669686; called by muse, varscan2
- TMSB10 | c.25G>A p.E9K | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.355); catalogued as COSV99252819; called by muse, mutect2, varscan2
- TREML2 | c.119A>C p.Q40P | Missense Mutation (SNP) | VAF 10/221 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as rs1342180774, COSV101530171; called by muse, mutect2
- TRIM58 | c.629C>A p.A210E | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV63571743; called by muse, mutect2, varscan2
- TTN | c.70547G>C p.R23516P (on ENST00000591111; = p.R16092P on NM_003319.4) | Missense Mutation (SNP) | VAF 11/111 reads (10%) | PolyPhen possibly damaging (0.758); catalogued as COSV100614979, COSV60113574; called by muse, mutect2, varscan2
- TTN | c.6368G>A p.R2123Q (on ENST00000591111; = p.R2077Q on NM_003319.4) | Missense Mutation (SNP) | VAF 16/55 reads (29%) | PolyPhen probably damaging (0.996); catalogued as rs530807674, COSV60205430; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- WDR72 | c.2502G>C p.L834F | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV100854533; called by muse, mutect2, varscan2
- ZFP36L2 | c.413A>T p.Q138L | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.47); PolyPhen benign (0.355); catalogued as COSV99143635; called by muse, mutect2
- ZNF20 | c.209G>A p.R70K | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV100503043; called by muse, mutect2, varscan2
- ZNF473 | c.1649T>A p.I550N | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.216); catalogued as COSV99568856; called by muse, mutect2
- ZNF473 | c.1650C>G p.I550M | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.364); catalogued as COSV99568857; called by muse, mutect2
- DIDO1 | c.1425dup p.E476Rfs*15 | Frame Shift Ins (INS) | VAF 26/80 reads (33%) | called by mutect2, varscan2
- KMT2D | c.9156dup p.T3053Yfs*2 | Frame Shift Ins (INS) | VAF 15/52 reads (29%) | called by mutect2, pindel, varscan2
- TCEAL3 | c.412_414del p.E138del | In Frame Del (DEL) | VAF 54/111 reads (49%) | called by pindel, varscan2
- ABCB4 | c.3201G>T p.L1067= | Silent (SNP) | VAF 38/153 reads (25%) | catalogued as COSV99710509; called by muse, mutect2, varscan2
- ADAM2 | c.1494C>T p.D498= | Silent (SNP) | VAF 11/87 reads (13%) | catalogued as COSV99697370; called by muse, mutect2, varscan2
- ANKS1B | c.816G>A p.Q272= | Silent (SNP) | VAF 38/108 reads (35%) | catalogued as COSV100245802; called by muse, mutect2, varscan2
- BCAN | c.99C>T p.R33= | Silent (SNP) | VAF 5/28 reads (18%) | catalogued as COSV61257575; called by muse, mutect2, varscan2
- BCL9 | c.2793T>A p.P931= | Silent (SNP) | VAF 17/138 reads (12%) | catalogued as COSV99325205; called by muse, mutect2, varscan2
- CELA3B | c.708C>G p.T236= | Silent (SNP) | VAF 11/43 reads (26%) | catalogued as COSV100448770, COSV100448896; called by muse, mutect2, varscan2
- EYA4 | c.477A>G p.T159= | Silent (SNP) | VAF 28/137 reads (20%) | catalogued as COSV100765928; called by muse, mutect2, varscan2
- FAM135B | c.921G>T p.L307= | Silent (SNP) | VAF 18/50 reads (36%) | catalogued as COSV99424264; called by muse, mutect2, varscan2
- GRM3 | c.237C>T p.I79= | Silent (SNP) | VAF 48/171 reads (28%) | catalogued as COSV100862578; called by muse, mutect2, varscan2
- IFT140 | c.4251G>A p.P1417= | Silent (SNP) | VAF 7/17 reads (41%) | catalogued as rs773095902, COSV99247959; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KIN | c.282C>T p.V94= | Silent (SNP) | VAF 15/107 reads (14%) | catalogued as COSV101092583; called by muse, mutect2, varscan2
- LPXN | c.282T>C p.D94= | Silent (SNP) | VAF 13/108 reads (12%) | catalogued as COSV101223054; called by muse, mutect2, varscan2
- P4HB | c.1005G>A p.T335= | Silent (SNP) | VAF 36/141 reads (26%) | catalogued as rs201567654, COSV58940391; called by muse, mutect2, varscan2
- PAK5 | c.1239G>A p.P413= | Silent (SNP) | VAF 21/69 reads (30%) | catalogued as COSV62026920; called by muse, mutect2, varscan2
- PRPF6 | c.2022C>T p.T674= | Silent (SNP) | VAF 8/58 reads (14%) | catalogued as rs151209735; called by mutect2, varscan2
- SI | c.4098C>T p.F1366= | Silent (SNP) | VAF 63/113 reads (56%) | catalogued as COSV52278197; called by muse, mutect2, varscan2
- SLC25A47 | c.300C>G p.L100= | Silent (SNP) | VAF 18/79 reads (23%) | catalogued as rs779650320, COSV100836505; called by muse, mutect2, varscan2
- SYT9 | c.465G>A p.Q155= | Silent (SNP) | VAF 12/27 reads (44%) | catalogued as rs1367459073, COSV100608273; called by muse, mutect2, varscan2
- XIRP2 | c.4398A>G p.L1466= (on ENST00000628543; = p.L1641= on NM_152381.6) | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as COSV99743300; called by muse, mutect2
- AC073310.1 | n.780G>C | RNA (SNP) | VAF 79/198 reads (40%) | called by muse, mutect2, varscan2
- SSPOP | n.9466del | RNA (DEL) | VAF 5/25 reads (20%) | called by mutect2, pindel, varscan2
